Somatic mutation profile of tumor specimen MP2PRT-PAUFJF-TMP1-A (aliquot MP2PRT-PAUFJF-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUFJF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,214 days).
Specimen MP2PRT-PAUFJF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad4e3670-7d49-49dc-8a57-4c2106270a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFJF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFJF-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40abed03-bc90-44a4-aa69-4a9d77a69d67

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 33/308 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/418 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 78/362 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LONRF2 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV66539766; called by muse, mutect2, varscan2
- MTSS1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 153/403 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52675929; called by muse, mutect2, varscan2
- PPARA | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs761530163; called by muse, mutect2
- WIPF3 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs375804779; called by muse, varscan2
- FAT4 | c.12155C>T p.T4052I | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FMOD | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 136/350 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- IFNLR1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 37/533 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NOTCH3 | c.4608C>G p.S1536R | Missense Mutation (SNP) | VAF 38/762 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- PAX5 | c.767_774dup p.E259Sfs*22 | Frame Shift Ins (INS) | VAF 66/300 reads (22%) | called by mutect2, varscan2
- A1CF | c.21C>T p.S7= | Silent (SNP) | VAF 82/313 reads (26%) | catalogued as rs559886617; called by muse, mutect2, varscan2
- FIGN | c.1821C>T p.T607= | Silent (SNP) | VAF 39/335 reads (12%) | catalogued as rs2231906; called by muse, mutect2, varscan2
- TTC39A | c.999+244T>C | Intron (SNP) | VAF 83/356 reads (23%) | catalogued as rs1319616040; called by muse, mutect2, varscan2
